Somatic mutation profile of tumor specimen TARGET-10-PARPYJ-09A (aliquot TARGET-10-PARPYJ-09A-01D) from TARGET case TARGET-10-PARPYJ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.4 years (2,719 days).
Specimen TARGET-10-PARPYJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42fbe74a-0959-4380-9b2b-49dcdf761a7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARPYJ-14A (Bone Marrow Normal), aliquot TARGET-10-PARPYJ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a85a0357-cd21-4749-9656-12978f6df7df

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, 3'UTR 1, Intron 1, 5'UTR 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STAT5B | c.1924A>C p.N642H | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); catalogued as rs938448224, COSV53180204; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CACNA1D | c.1511G>A p.R504H (on ENST00000350061 / NM_001128840.3; = p.R524H on NM_000720.4) | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.5); PolyPhen benign (0.043); catalogued as COSV55449352; called by muse, mutect2, varscan2
- GLI2 | c.1178C>T p.T393M | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as rs571690193, COSV58045775; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDM6A | c.3331delinsGG p.R1111Gfs*40 | Frame Shift Ins (INS) | VAF 33/89 reads (37%) | catalogued as COSV65038074, COSV65038305, COSV65040911, COSV65042699; called by pindel, varscan2*
- NFS1 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs148627243; called by muse, mutect2, varscan2
- RHBDF2 | c.265G>C p.V89L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.072); catalogued as COSV57421357; called by muse, mutect2, varscan2
- SARS1 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT tolerated (0.63); PolyPhen benign (0.108); catalogued as rs759249402, COSV52321830; called by muse, mutect2, varscan2
- SH3GL1 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 16/17 reads (94%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.839); catalogued as COSV53658322; called by muse, mutect2, varscan2
- TPTE | c.1451A>T p.N484I (on ENST00000618007 / NM_199261.4; = p.N466I on NM_199259.4) | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as rs1408933974; called by mutect2, varscan2
- WNT6 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1369314126, COSV52110547; called by muse, mutect2, varscan2
- NEURL1B | c.459C>T p.R153= | Silent (SNP) | VAF 14/32 reads (44%) | called by mutect2, varscan2
- PTPRM | c.3621C>T p.I1207= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs769282849; called by muse, mutect2, varscan2
- ARHGAP23P1 | n.835T>C | RNA (SNP) | VAF 6/51 reads (12%) | catalogued as rs1278215138; called by muse, varscan2
- RAPGEF5 | c.871-209A>C | Intron (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- SLC35F4 | c.-17G>A | 5'UTR (SNP) | VAF 15/30 reads (50%) | catalogued as rs113946933, COSV101620680; called by muse, mutect2
- SLC6A6 | c.*184_*185dup | 3'UTR (INS) | VAF 4/11 reads (36%) | catalogued as rs1350425426; called by mutect2, varscan2
